Somatic mutation profile of tumor specimen 0DVR7Z from CCDI case PBCMWR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,910 days).
Specimen 0DVR7Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b187deb-e014-471a-83ae-72b915ff8650.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVR5T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46604410-d75e-4d4c-966c-a671e2ac3ba8

The open-access MAF lists 69 somatic variants for this specimen: 53 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 7, Intron 5, Nonsense Mutation 4, 3'UTR 3, Splice Region 2, Splice Site 2, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRS | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 245/491 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs756440961; called by muse, mutect2, varscan2
- AKNA | c.3137C>A p.P1046Q | Missense Mutation (SNP) | VAF 92/520 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs139755326; called by muse, mutect2, varscan2
- ATP10A | c.3499C>T p.R1167W | Missense Mutation (SNP) | VAF 108/476 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs188478723; called by muse, mutect2, varscan2
- AVPR2 | c.24C>T p.S8= | Splice Region (SNP) | VAF 78/436 reads (18%) | catalogued as rs201419746, COSV61686024; called by muse, mutect2, varscan2
- BCAS3 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 247/797 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs866983064; called by muse, mutect2, varscan2
- CAPZA3 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 159/1038 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs371829412; called by muse, mutect2, varscan2
- CBLB | c.1204-1G>C p.X402_splice | Splice Site (SNP) | VAF 126/601 reads (21%) | catalogued as COSV51423875, COSV99913819; called by muse, mutect2, varscan2
- CD1E | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 230/1855 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs750925859, COSV63770860; called by muse, mutect2, varscan2
- COL6A6 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 94/506 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs774730504, COSV62039022; called by muse, mutect2, varscan2
- DNAH1 | c.4366G>A p.G1456S | Missense Mutation (SNP) | VAF 175/426 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs766683439; called by muse, mutect2, varscan2
- EHBP1 | c.2563G>T p.D855Y | Missense Mutation (SNP) | VAF 331/806 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs757260350; called by muse, mutect2, varscan2
- EIPR1 | c.862G>C p.V288L | Missense Mutation (SNP) | VAF 89/500 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs764415417; called by muse, mutect2, varscan2
- FCRL6 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 118/1560 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV58942980; called by muse, mutect2
- GPR156 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 68/248 reads (27%) | catalogued as rs553212940, COSV59940911; called by muse, mutect2, varscan2
- GPR157 | c.597+7G>A | Splice Region (SNP) | VAF 228/414 reads (55%) | catalogued as rs185295163; called by muse, mutect2, varscan2
- HMCN1 | c.9314_9315del p.H3105Rfs*6 | Frame Shift Del (DEL) | VAF 315/2310 reads (14%) | catalogued as rs753491403; called by mutect2, varscan2
- HOXD13 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.831); catalogued as rs1169105229; called by muse, mutect2, varscan2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 52/246 reads (21%) | catalogued as rs761880048; called by mutect2, varscan2
- NT5C2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV58418569; called by muse, mutect2, varscan2
- OBSCN | c.14368G>A p.D4790N | Missense Mutation (SNP) | VAF 125/738 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs1018940318; called by muse, mutect2, varscan2
- OSBPL1A | c.1813-1G>A p.X605_splice (on ENST00000319481 / NM_080597.4; = p.X92_splice on NM_018030.4) | Splice Site (SNP) | VAF 34/242 reads (14%) | catalogued as COSV60201660; called by muse, mutect2, varscan2
- PKN1 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 100/330 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367610820; called by muse, mutect2, varscan2
- PLCD1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 150/621 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs148282341; called by muse, mutect2, varscan2
- PLCG2 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 92/555 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1468421212; called by muse, mutect2, varscan2
- PUS7 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.591); catalogued as rs766160107, COSV100708571; called by muse, mutect2, varscan2
- RASGEF1A | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 137/354 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1024709428; called by muse, mutect2, varscan2
- RXRG | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 249/1888 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63231499; called by muse, mutect2, varscan2
- THBS4 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 134/754 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs761208787; called by muse, mutect2, varscan2
- TTC28 | c.6221G>A p.R2074Q | Missense Mutation (SNP) | VAF 203/614 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); catalogued as rs763343450, COSV101195215; called by muse, mutect2, varscan2
- ADGRF2 | c.1037C>A p.T346N (on ENST00000296862 / NM_001368115.2; = p.T278N on NM_153839.7) | Missense Mutation (SNP) | VAF 122/672 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBL | c.887G>A p.S296N | Missense Mutation (SNP) | VAF 226/485 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLB | c.1981G>T p.G661* | Nonsense Mutation (SNP) | VAF 462/1087 reads (43%) | called by muse, mutect2, varscan2
- CDKL5 | c.2015C>G p.T672S | Missense Mutation (SNP) | VAF 59/526 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRYBG3 | c.370T>C p.F124L | Missense Mutation (SNP) | VAF 356/1009 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX11 | c.2843G>A p.S948N | Missense Mutation (SNP) | VAF 88/536 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO30 | c.766A>T p.N256Y | Missense Mutation (SNP) | VAF 322/1071 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.009); called by mutect2, varscan2
- HAS2 | c.1380A>T p.K460N | Missense Mutation (SNP) | VAF 523/1382 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- HECTD4 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 260/648 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- LACTB | c.921A>C p.L307F | Missense Mutation (SNP) | VAF 183/431 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- LIPH | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 186/831 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- MYH1 | c.2812G>T p.A938S | Missense Mutation (SNP) | VAF 168/414 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.031); called by mutect2, varscan2
- NVL | c.1959C>G p.N653K | Missense Mutation (SNP) | VAF 293/1935 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAXBP1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 413/1266 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHB13 | c.1934A>C p.K645T | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- PRR23A | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 111/514 reads (22%) | called by muse, mutect2, varscan2
- SMUG1 | c.730A>T p.N244Y | Missense Mutation (SNP) | VAF 66/425 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SMUG1 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SPTA1 | c.6783G>T p.Q2261H | Missense Mutation (SNP) | VAF 281/1812 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TCP10L2 | c.423_428del p.K141_A143delinsN | In Frame Del (DEL) | VAF 140/1184 reads (12%) | called by mutect2, varscan2
- TTC21A | c.2480T>C p.V827A | Missense Mutation (SNP) | VAF 146/635 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS4B | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 99/502 reads (20%) | called by muse, mutect2, varscan2
- ZFP91 | c.1565G>C p.G522A | Missense Mutation (SNP) | VAF 281/528 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ZNF529 | c.1288G>C p.A430P | Missense Mutation (SNP) | VAF 213/683 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR89B | c.171C>G p.L57= | Silent (SNP) | VAF 314/2501 reads (13%) | called by muse, mutect2, varscan2
- NEU4 | c.1212C>T p.R404= (on ENST00000391969 / NM_001167602.3; = p.R416= on NM_080741.4) | Silent (SNP) | VAF 140/337 reads (42%) | catalogued as rs761009589; called by muse, mutect2
- OBSCN | c.21210C>T p.P7070= | Silent (SNP) | VAF 153/935 reads (16%) | catalogued as rs933320915, COSV62468879; called by muse, mutect2, varscan2
- SERPINA11 | c.36G>A p.G12= | Silent (SNP) | VAF 114/428 reads (27%) | called by muse, mutect2, varscan2
- SPAG8 | c.1095G>T p.V365= | Silent (SNP) | VAF 56/311 reads (18%) | called by muse, mutect2, varscan2
- TACC2 | c.7425G>A p.A2475= (on ENST00000334433; = p.A553= on NM_006997.4) | Silent (SNP) | VAF 106/559 reads (19%) | catalogued as rs769368467; called by muse, mutect2, varscan2
- ZSCAN5B | c.39A>G p.G13= | Silent (SNP) | VAF 106/325 reads (33%) | called by muse, mutect2, varscan2
- BCLAF3 | c.2106+68T>C | Intron (SNP) | VAF 31/150 reads (21%) | called by muse, mutect2
- CBR1 | c.*43G>C | 3'UTR (SNP) | VAF 69/198 reads (35%) | called by muse, mutect2, varscan2
- CCAR2 | c.2332+31G>A | Intron (SNP) | VAF 95/336 reads (28%) | called by muse, mutect2, varscan2
- CSAG3 | c.*35G>T | 3'UTR (SNP) | VAF 114/1383 reads (8%) | called by muse, mutect2
- DHRS12 | c.706+444G>A | Intron (SNP) | VAF 155/489 reads (32%) | catalogued as COSV54472828; called by muse, mutect2, varscan2
- GRIPAP1 | c.2278+26G>T | Intron (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- MYH3 | c.5659-39C>T | Intron (SNP) | VAF 119/306 reads (39%) | catalogued as rs1457922563; called by muse, mutect2, varscan2
- RBP3 | c.-91G>T | 5'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, varscan2
- TRIM15 | c.*27C>G | 3'UTR (SNP) | VAF 57/190 reads (30%) | catalogued as rs761622621; called by muse, mutect2, varscan2
